Somatic mutation profile of tumor specimen TARGET-20-PASSGX-09A (aliquot TARGET-20-PASSGX-09A-01D) from TARGET case TARGET-20-PASSGX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.4 years (6,351 days).
Specimen TARGET-20-PASSGX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b628011-f5d2-4315-9088-28fff67b3597.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSGX-14A (Bone Marrow Normal), aliquot TARGET-20-PASSGX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abb8a118-8bfc-4e4e-b5f3-5ebbe1a8461a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NLRP3 | c.2819A>G p.K940R | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs201580005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.4843G>C p.D1615H | Missense Mutation (SNP) | VAF 113/217 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs375040526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF1 | c.*936A>C | 3'UTR (SNP) | VAF 130/272 reads (48%) | called by muse, mutect2, varscan2
- PRUNE2 | c.*468C>T | 3'UTR (SNP) | VAF 106/196 reads (54%) | called by muse, mutect2, varscan2
- SCRN3 | c.*1205A>G | 3'UTR (SNP) | VAF 140/311 reads (45%) | catalogued as rs1390509267; called by muse, mutect2, varscan2
